Surgical pathology report (de-identified scan), TCGA case TCGA-66-2787, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2787-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Upper lobe left and others

Clinical diagnosis and question

Bronchial carcinoma left upper lobe S1 and 2

REPORT ON FINDINGS**Macroscopy**

1) Left upper lobe: inflated, fixed resected tissue measuring $26 \times 17 \times 8$ cm with hazy, clouded, moderately thick pleura with reticulate patches in places and diffuse, dark gray marking in places. Circumscribed thickening over the apex, adhesion residue medially and clip ligatures there. Bronchus displaced centrally 5 mm proximally of the bifurcation of the lingula bronchus. Grayish brown discolored tumor tissue projecting from the ostium of B2. Outflow region of B2 greatly raised up to 1.8 cm and filled with grayish white, solid tumor tissue, 2.6 cm at the greatest extent, In the B1/2 division point region infiltration of the bronchial walls, the central section of B1 severely twisted here, but without detectable incursion into the lumen. A lymph node by the distal upper lobe bronchus in parabronchial position and marginally bordering the tumor, apparently not infiltrated by the tumor, section surfaces with black pigment in places. In segment 2 a large vascular branch segment ally displaced by compact, brownish yellow to reddish material. Severely ectasic bronchial branch, distally of the tumor in segment 2, as far as the periphery, stuffed with pale yellow invisible material. Pulmonary parenchyma centrally in segment 2 and extending into segment 1 with brownish yellow to pale gray brownish thickening, peripherally in segment 2 isolated small, golden yellow, indistinctly delineated sub-pleural induration foci. In the ventral apical region further, relatively sharply defined, peripheral, whitish tumor node in the mantle zone, 7 mm in size. Further into segment 1 below the adhesion zone described, towards the apex, small, pigmented sub-pleural lymph nodes 4 mm in size. Ventrally in segment 1, extending into the border region of S3, sub-pleural spongiform or honeycomb parenchymal structure with porous induration in places, isolated large cysts or cystic systems in segment 1 with greatest extension up to just 2 cm. B3 and bronchial bifurcations of the lingula clear as far as the periphery, parenchyma with normal section surfaces in the lingula.

2) Pleura biopsy: 1.2×0.7 cm in size, flat area between 0.2 and 0.6 cm thick, surface projected forward at one end by a whitish, rough node 0.5 cm in size, section surface predominantly whitish, brownish in the center.

3) Lobar LN (item 12) left: blackish node 0.8 cm in size with some surrounding tissue.

4) Inter-lobar LN (item 11) left: blackish node 0.5 cm in size with some surrounding tissue.

5) Hilar LN (item 10) left: four blackish nodes between 0.2 and 1 cm in size. Nodes with some surrounding tissue.

6) Pulmonary ligament LN (item 9) left: blackish node 1 cm in size with some surrounding tissue.

7) Deep paratracheal LN (item 4) left: lesioned blackish node 0.9 cm in size with some surrounding tissue.

[page 2 of 2]
Examined

1) Central bronchial resection line (rapid section residue) + vascular displacement borders, 2 sections of tumor with color marking of peribronchial/hilar resection surface, further tumor section/bifurcation of B2, 2 sections with extended bronchial sections distally of the tumor, 2 peripheral portions of segment 2 with yellowish areas, small tumor nodes in segment 1, sub-pleural lymph node in segment 1, further section of S1 with bullae, S1/.3 with sub-pleural induration.

2) - 7) each total material (preparation halved in 2)), 17 blocks, partly Elastica-v.Gieson, PAS, diastasis-PAS.

Microscopy

1) Intraoperative immediate evaluation [REDACTED] bronchial mucosa and wall free of tumor at the resection border, desquamation of carcinoma cells only in the lumen.

Description of the histological and cytological findings omitted for reasons of capacity.

EVALUATION

Central, partly endobronchial, obliterating growth of bronchopulmonary, histologically poorly differentiated, large cell, nonkeratinizing squamous cell carcinoma (WHO category 1.3.1) with displacement of B2 and narrowing of B1. Resection border of bronchus and vessels, hilar resection surface, visceral pleura and all identified and removed lymph nodes of samples 1) and 2) - 7) including the lymph nodes from sample 1) local subpleural area in S1 region tumor-free. Peripheral to the tumor in S2 consecutive bronchiectases and here and in S1 focal chronically organizing retention pneumonia.

Also peripheral pulmonary hematoma in S1, focal, subpleural, bullous pulmonary emphysema and focal, uncharacteristic subpleural area of scarring at the transition of S1 to S3. In sample 2) nodular, partially calcified, hypocellular fibrous zone of the parietal pleura.

TNM classification pT1 pN0 R0, stage IA.

Morphology:	80703
Topography:	028500
Morphology:	8070/3
Topography:	C34.1
Grading:	3
Stage:	T1N0MXR0

Source: NCI Genomic Data Commons file b7bb9eb5-295e-47a3-9282-41b47bc4704b (TCGA-66-2787.AA241183-BB71-4B0C-8D00-E10EC86145E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).